MMRF case MMRF_1858 — Multiple Myeloma CoMMpass Study (MMRF-COMMPASS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Plasma Cell Tumors; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): first treatment.
https://portal.gdc.cancer.gov/cases/6a527afa-c05e-4e7f-99f6-cae65423ee68

Demographics
Sex at birth: male; Race: black or african american; Ethnicity: not hispanic or latino; Age at index: 62 years; Vital status: Alive.

Diagnoses (1)
1. Multiple myeloma: ICD-O-3 morphology code: 9732/3; Tissue or organ of origin: Bone marrow; Site of resection or biopsy: Bone marrow; Age at diagnosis: 62.8 years (22,939 days); ISS stage: III; Days to last known disease status: 1,090 days (3.0 years); Days to last follow up: 1,090 days (3.0 years).
   Treatment given: Therapeutic agents: Bortezomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 1 day; Days to treatment end: 25 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 76 days; Days to treatment end: 153 days.
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: First line of therapy; Days to treatment start: 76 days; Days to treatment end: 327 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: First line of therapy; Days to treatment start: 153 days; Days to treatment end: 327 days.
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 744 days (2.0 years); Days to treatment end: 909 days (2.5 years).
   Treatment given: Therapeutic agents: Lenalidomide; Regimen or line of therapy: Second line of therapy; Days to treatment start: 744 days (2.0 years); Days to treatment end: 1,033 days (2.8 years).
   Treatment given: Therapeutic agents: Dexamethasone; Regimen or line of therapy: Second line of therapy; Days to treatment start: 910 days (2.5 years); Days to treatment end: 1,033 days (2.8 years).
   Treatment given: Therapeutic agents: Carfilzomib + Cyclophosphamide + Dexamethasone; Regimen or line of therapy: Third line of therapy; Days to treatment start: 1,037 days (2.8 years).

Molecular and laboratory tests (laboratory values one line per visit day; values rounded to 3 significant figures where GDC's unit conversion carried more)
- Day -2 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 789 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.1 mg/dL; Immunoglobulin G 11.1 g/L; Immunoglobulin A 1.16 g/L; Immunoglobulin M 0.64 g/L; Beta 2 Microglobulin 7.3 µg/mL; Hemoglobin 6.63 mmol/L; Leukocytes 5.2 ×10⁹/L; Absolute Neutrophil 2 ×10⁹/L; Platelets 114 ×10⁹/L; Creatinine 172 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.7 mmol/L; Albumin 35 g/L; Total Protein 6.8 g/dL; Glucose 5.12 mmol/L; C-Reactive Protein 3.8 mg/dL.
- Day 99 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 296 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 1.96 mg/dL; Hemoglobin 6.32 mmol/L; Leukocytes 4.7 ×10⁹/L; Absolute Neutrophil 2.21 ×10⁹/L; Platelets 97 ×10⁹/L; Creatinine 124 µmol/L; Blood Urea Nitrogen 4.64 mmol/L; Calcium 2.43 mmol/L; Albumin 39 g/L; Total Protein 6.9 g/dL; Glucose 5.28 mmol/L.
- Day 153 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 1.69 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.51 mg/dL; Immunoglobulin G 8.61 g/L; Immunoglobulin A 0.89 g/L; Immunoglobulin M 0.54 g/L; Hemoglobin 7.44 mmol/L; Leukocytes 4.3 ×10⁹/L; Absolute Neutrophil 2.49 ×10⁹/L; Platelets 143 ×10⁹/L; Creatinine 89.3 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.18 mmol/L; Albumin 34 g/L; Total Protein 6 g/dL; Glucose 5.12 mmol/L.
- Day 263 (ECOG 2): M Protein 0 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.94 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.36 mg/dL; Hemoglobin 8.06 mmol/L; Leukocytes 7.7 ×10⁹/L; Absolute Neutrophil 3.69 ×10⁹/L; Platelets 345 ×10⁹/L; Creatinine 153 µmol/L; Blood Urea Nitrogen 6.43 mmol/L; Calcium 2.48 mmol/L; Albumin 37 g/L; Total Protein 8 g/dL; Glucose 4.73 mmol/L.
- Day 354 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 2.57 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.92 mg/dL; Hemoglobin 7.01 mmol/L; Leukocytes 5.1 ×10⁹/L; Absolute Neutrophil 2.2 ×10⁹/L; Platelets 183 ×10⁹/L; Creatinine 143 µmol/L; Blood Urea Nitrogen 5.36 mmol/L; Calcium 2.33 mmol/L; Albumin 35 g/L; Total Protein 6.6 g/dL; Glucose 4.51 mmol/L.
- Day 439 (ECOG 2): M Protein 0.1 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 2.66 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.66 mg/dL; Hemoglobin 7.07 mmol/L; Leukocytes 5.3 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 116 ×10⁹/L; Creatinine 173 µmol/L; Blood Urea Nitrogen 9.28 mmol/L; Calcium 2.5 mmol/L; Albumin 40 g/L; Total Protein 7.3 g/dL; Glucose 4.57 mmol/L.
- Day 552 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 3.48 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.67 mg/dL; Immunoglobulin G 14.5 g/L; Immunoglobulin A 2.54 g/L; Immunoglobulin M 0.708 g/L; Hemoglobin 7.75 mmol/L; Leukocytes 7.2 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 52 ×10⁹/L; Creatinine 146 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.5 mmol/L; Albumin 41 g/L; Total Protein 8.1 g/dL; Glucose 4.9 mmol/L.
- Day 629 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 6.46 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.38 mg/dL; Immunoglobulin G 16.3 g/L; Immunoglobulin A 3.28 g/L; Immunoglobulin M 0.582 g/L; Hemoglobin 8 mmol/L; Leukocytes 5.4 ×10⁹/L; Absolute Neutrophil 3.4 ×10⁹/L; Platelets 175 ×10⁹/L; Creatinine 129 µmol/L; Blood Urea Nitrogen 6.78 mmol/L; Calcium 2.4 mmol/L; Albumin 40 g/L; Total Protein 8.1 g/dL; Glucose 6.6 mmol/L.
- Day 742 (ECOG 2): M Protein 0.3 g/dL; Serum Free Immunoglobulin Light Chain, Kappa 68.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 2.47 mg/dL; Immunoglobulin G 14.1 g/L; Immunoglobulin A 2.12 g/L; Immunoglobulin M 0.408 g/L; Hemoglobin 7.69 mmol/L; Leukocytes 6.2 ×10⁹/L; Absolute Neutrophil 3.2 ×10⁹/L; Platelets 199 ×10⁹/L; Creatinine 147 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.48 mmol/L; Albumin 35 g/L; Total Protein 7 g/dL; Glucose 5.12 mmol/L.
- Day 816 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 17.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 5.13 mg/dL; Immunoglobulin G 12.9 g/L; Immunoglobulin A 2.7 g/L; Immunoglobulin M 0.431 g/L; Hemoglobin 7.01 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 4.5 ×10⁹/L; Platelets 233 ×10⁹/L; Creatinine 151 µmol/L; Blood Urea Nitrogen 13.9 mmol/L; Calcium 2.28 mmol/L; Albumin 35 g/L; Total Protein 7.2 g/dL; Glucose 5.01 mmol/L.
- Day 910 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 16.3 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.72 mg/dL; Immunoglobulin G 10.2 g/L; Immunoglobulin A 3.88 g/L; Immunoglobulin M 0.401 g/L; Hemoglobin 7.25 mmol/L; Leukocytes 8.2 ×10⁹/L; Absolute Neutrophil 6 ×10⁹/L; Platelets 188 ×10⁹/L; Creatinine 122 µmol/L; Blood Urea Nitrogen 2.5 mmol/L; Calcium 2.25 mmol/L; Albumin 34 g/L; Total Protein 6.3 g/dL; Glucose 5.23 mmol/L.
- Day 994 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 97.5 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 3.18 mg/dL; Immunoglobulin G 8.66 g/L; Immunoglobulin A 2.72 g/L; Immunoglobulin M 0.232 g/L; Hemoglobin 7.5 mmol/L; Leukocytes 6.5 ×10⁹/L; Absolute Neutrophil 4.3 ×10⁹/L; Platelets 141 ×10⁹/L; Creatinine 148 µmol/L; Blood Urea Nitrogen 7.14 mmol/L; Calcium 2.4 mmol/L; Albumin 39 g/L; Total Protein 7.2 g/dL; Glucose 6.77 mmol/L.
- Day 1,090 (ECOG 2): Serum Free Immunoglobulin Light Chain, Kappa 20.7 mg/dL; Serum Free Immunoglobulin Light Chain, Lambda 0.879 mg/dL; Immunoglobulin G 4.59 g/L; Immunoglobulin A 0.458 g/L; Immunoglobulin M 0.2 g/L; Hemoglobin 6.2 mmol/L; Leukocytes 2.9 ×10⁹/L; Absolute Neutrophil 1.5 ×10⁹/L; Platelets 67 ×10⁹/L; Creatinine 149 µmol/L; Blood Urea Nitrogen 5 mmol/L; Calcium 2.4 mmol/L; Albumin 38 g/L; Total Protein 6 g/dL; Glucose 6 mmol/L.

Other clinical attributes
- Day -2: Weight: 60 kg; Height: 165 cm.

Family history
- Relative with cancer history: no.

Biospecimens (2 samples)
- Sample MMRF_1858_1_BM_CD138pos: Sample type: Primary Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Bone Marrow NOS; Days to sample procurement: -2 days.
- Sample MMRF_1858_1_PB_Whole: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS; Days to sample procurement: -2 days.
